Surgical pathology report (de-identified scan), TCGA case TCGA-06-0147, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0147-01A (Primary Tumor).

PATH.NO: [REDACTED]

NAME: [REDACTED]

MED. REC. NO [REDACTED]

AGE/SEX: [REDACTED]

SURGERY DATE: [REDACTED]

PHYSICIAN: [REDACTED]

RECEIVE DATE: [REDACTED]

COPY TO:

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY: GLIOBLASTOMA MULTIFORME, MIB-1, ABOUT 10%.

Operation/Specimen: Right partial tumor.

Clinical History and Pre-Op Dx: Right partial tumor.

GROSS PATHOLOGY: Multiple small tissue fragments. FROZEN SECTION
DIAGNOSIS: GLIOMA, in #1-2.

MICROSCOPIC: Sections show large area of tumor necrosis surrounded by anaplastic astrocytes and vascular proliferation together with macrophages and mononuclear cells, the latter likely due to previous biopsy. The MIB-1 labelling index is about 10%.

[REDACTED] [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file ef21407e-13c0-4340-b94d-c2df2016a9a0 (TCGA-06-0147.2B37E144-879C-4423-AF3F-B548DB00E57C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).